Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H6, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H6-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. LIVER, SEGMENT FIVE, LIVER TUMOR, AND GALLBLADDER, RESECTION:
Hepatocellular carcinoma, moderately-differentiated.
(See Key Pathological Findings).
Minimal tumor necrosis (less than 1%)
Uninvolved liver parenchyma with chronic triaditis.
Chronic cholecystitis and cholelithiasis with no evidence of malignancy.
Cystic duct margin free of tumor.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Comment

The trichrome stain highlights the mild to moderate portal fibrosis. The reticulin stain shows interrupted reticulin framework in the tumor component. The iron stain is negative. The tumor cells are positive for HepPar-1, and negative for Alpha Fetoprotein, cytokeratin 7 and cytokeratin 20. All of the stains were performed with appropriate controls. These results support the above diagnosis.

Key Pathological Findings

- A: Liver, Resection v.
Specimen:
Liver
Gallbladder
PROCEDURE:
*Minor hepatectomy (less than 3 segments)
TUMOR SIZE:
Greatest dimension: 7.3 cm
*Additional dimensions: 5.6 x 5.0 cm
TUMOR FOCALITY:
Solitary (specify location): segment 5
HISTOLOGIC TYPE:
Hepatocellular carcinoma
HISTOLOGIC GRADE:
GII: Moderately differentiated
TUMOR EXTENSION (select all that apply):
Tumor confined to liver
PRIMARY TUMOR (pT):

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
JSD 4/28/14

[page 2 of 2]
pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
REGIONAL LYMPH NODES (pN):
pNX: Cannot be assessed
DISTANT METASTASIS (pM):
pMX: Cannot be assessed
MARGINS:
Parenchymal margin uninvolved by invasive carcinoma
*VENOUS (LARGE VESSEL) INVASION (V):
*Absent
*ADDITIONAL PATHOLOGIC FINDINGS:
Chronic triaditis

Specimen(s) Received

A SEGMENT FIVE OF LIVER, LIVER TUMOR, GALLBLADDER

Clinical History

HEPATOCELLULAR CARCINOMA

Preoperative Diagnosis

Hepatocellular carcinoma.

Intraoperative Consultation

A: SEGMENT OF LIVER (INTRAOPERATIVE CONSULT):
Tumor at 1.8 cm from margin.

Comment: This gross consultation/result was communicated to and acknowledged by _____ in
Frozen section room at _____

I, _____, have performed the intraoperative consultation and issued the above
diagnosis.

Gross Description

A. The specimen is received fresh, labeled "segment 5 of liver, liver tumor, gallbladder" and consists of a liver with attached gallbladder. The liver is 190.9 grams, 12.0 x 7.5 x 5.0 cm. There is a 7.3 x 5.6 x 5.0 cm well circumscribed yellow-tan, lobulated mass with a central area of hemorrhage. The mass abuts and distends the capsule. The mass is 1.8 cm from closest surgical margin which is inked blue. The remaining liver parenchyma is brown without nodularity. The capsule is otherwise smooth with no adhesions or nodules. The gallbladder is 15.5 x 7.0 x 3.5 cm. The serosa is slightly congested with a small amount of adhesions. The wall averages 0.1 cm in thickness. The mucosa is flattened. The lumen contains a dark yellow, viscous bile and a 0.8 x 0.8 x 0.5 cm aggregate of homogenous black, nodular, friable stones, which are up to 0.7 cm in greatest dimension.

Representative sections are submitted as follows:

- A1-A2: Mass perpendicular to surgical margin with adjacent normal parenchyma.
- A3-A4: Mass with capsule.
- A5: Mass with central area of hemorrhage
- A6-A7: Random sections of mass
- A8: Normal parenchyma
- A9: Cystic duct margin
- A10: Gallbladder

A portion of tissue is submitted to Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file 6d7c8427-9d1e-47e6-91a4-63452e410032 (TCGA-2Y-A9H6.0B39CB6A-D208-4128-AB46-50C7DB072865.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).